Surgical pathology report (de-identified scan), TCGA case TCGA-FY-A3RA, project TCGA-THCA (Thyroid Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-FY-A3RA-01A (Primary Tumor).

[page 1 of 2]
Surg Path Final Report

* Final Report *

* Final Report *

SURG PATH FINAL REPORT

SURGICAL PATHOLOGY

Collected:
Accession: XXXXXXXXXX
Physician: XXXXXXXXXX

PROCEDURE

Total thyroidectomy.

SPECIMEN:

- A. Left thyroid. Send fresh. No frozen section.
- B. Right thyroid.

HISTORY

Thyroid cancer.

GROSS

A. The specimen is submitted fresh in a container labeled with the patient's name and "left thyroid." A thyroid lobe measures 5.3 x 3 x 2.7 cm. The specimen is inked and serially sectioned. A 4 cm in greatest dimension discrete encapsulated tan neoplasm has a bulging soft friable papillary cut surface. A portion is submitted for the project. Representative sections are submitted in four cassettes.

B. The specimen is received in formalin in a container labeled with the patient's name and "right thyroid." A 4.5 x 2 x 1.3 cm lobe of thyroid is serially sectioned and is grossly unremarkable. Representative sections are submitted in two cassettes.

MICROSCOPIC

Performed.

DIAGNOSIS

- A. Left thyroid, excision:
Papillary carcinoma (see summary below).
- B. Right thyroid, excision:
No significant abnormality.

THYROID CARCINOMA SUMMARY:

PROCEDURE: Total thyroidectomy.

SPECIMEN INTEGRITY: Right and left sides submitted separately.

SPECIMEN SIZE: See gross description.

1CD-03
carcinoma, papillary, thyroid
8260/3
Site: thyroid
C73.9 3-30-12
RD

Printed by:
Printed on:

Page 1 of 2
(Continued)

[page 2 of 2]
Surg Path Final Report

* Final Report *

TUMOR FOCALITY: Unifocal.
TUMOR LATERALITY: Left side.
TUMOR SIZE: 4 cm in greatest dimension.
HISTOLOGIC TYPE: Papillary carcinoma.
MARGINS: Negative for neoplasm.
TUMOR CAPSULE: Totally encapsulated.
CAPSULAR INVASION: Focal capsular invasion.
LYMPHOVASCULAR INVASION: Not identified.
EXTRATHYROIDAL EXTENSION: Not identified.
PATHOLOGIC STAGING (AJCC): pT2, pNx. 1

--- M.D. (Electronic Signature)

Completed Action List:

* Order by _____ on _____

Type: Surg Path Final Report
Date:
Status: Auth (Verified)
Title: SURG PATH FINAL REPORT
Encounter info:

Printed by:
Printed on:

Page 2 of 2
(End of Report)

Source: NCI Genomic Data Commons file d7769a3b-cdc1-4a32-bbd9-e4aac77e58c8 (TCGA-FY-A3RA.370C33BA-DDB3-4DA9-984E-68037C4C5D73.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).